Gene-level copy-number profile of tumor specimen TCGA-AA-A01K-01A from TCGA case TCGA-AA-A01K, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 74.0 years (27,029 days).
Specimen TCGA-AA-A01K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.962fb5ea-a32c-4f4f-bf04-26ccbd8edf44.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c3ffee93-14b2-48fa-ab97-569d5adff776

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 264; copy number 1: 18,478; copy number 2: 39,733; copy number 3: 1,333.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A01K-01A-01D-A008-01): tumor purity 0.54, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 210 genes in 78 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,933,320–43,991,170, 8 genes: ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2.
- chr1:47,216,290–47,440,691, 8 genes (within-gene range 0–1): TAL1, AL135960.1, STIL, CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2.
- chr1:78,889,764–79,282,124, 2 genes (within-gene range 0–1): ADGRL4, PSAT1P3.
- chr1:100,538,139–100,542,021, 1 gene: GPR88.
- chr1:109,504,178–109,509,738, 1 gene: AMIGO1.
- chr2:131,419,665–131,463,615, 5 genes: AC073869.6, GNAQP1, NOC2LP2, RHOQP2, AC073869.1.
- chr2:236,194,872–236,264,409, 2 genes (within-gene range 0–2): ASB18, RNU1-31P.
- chr3:71,675,414–71,785,206, 3 genes (within-gene range 0–1): EIF4E3, GPR27, PROK2.
- chr4:7,030,554–7,057,952, 3 genes: AC097382.2, CCDC96, TADA2B.
- chr5:7,367,929–7,391,907, 2 genes (within-gene range 0–2): AC027343.2, LINC02142.
- chr5:172,662,165–172,697,720, 2 genes: MIR5003, AC027309.1.
- chr5:179,614,178–179,634,784, 2 genes (within-gene range 0–1): HNRNPH1, Metazoa_SRP.
- chr6:1,312,098–1,324,022, 2 genes: FOXQ1, LINC01394.
- chr7:102,264,706–102,329,530, 4 genes: AC005088.1, SH2B2, MIR4285, AC091390.1.
- chr7:149,195,546–149,497,817, 11 genes (within-gene range 0–2): ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746.
- chr8:1,758,208–1,764,508, 2 genes: AC100810.3, AC100810.1.
- chr10:91,152,605–91,161,315, 2 genes: NUDT9P1, AL731553.1.
- chr11:23,403,805–23,419,190, 2 genes: WIZP1, MIR8054.
- chr11:66,040,765–66,069,619, 4 genes: GAL3ST3, AP006287.3, SF3B2, AP006287.2.
- chr11:74,738,478–74,746,114, 2 genes: AP001324.2, AP001324.1.
- chr11:119,044,188–119,067,698, 3 genes: HYOU1, AP003392.4, AP003392.5.
- chr11:130,032,866–130,041,071, 2 genes: ELOBP2, AP003041.2.
- chr12:51,951,699–52,015,889, 3 genes: ACVR1B, RNU6-574P, TAMALIN.
- chr13:109,752,695–109,808,252, 2 genes (within-gene range 0–2): IRS2, AL162497.1.
- chr15:78,250,502–78,282,196, 2 genes: AC090607.3, DNAJA4.
- chr17:38,419,280–38,512,385, 2 genes (within-gene range 0–2): ARHGAP23, AC244153.1.
- chr17:46,193,576–46,268,694, 5 genes: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr17:61,393,456–61,413,280, 3 genes (within-gene range 0–2): TBX2-AS1, TBX2, LINC02875.
- chr17:72,627,231–72,644,490, 2 genes: RPL32P33, AC080037.2.
- chr17:76,703,632–76,726,799, 4 genes (within-gene range 0–2): RNY4P36, AC005837.4, JMJD6, AC005837.3.
- chr18:8,688,022–8,707,621, 2 genes: TOMM20P3, GACAT2.
- chr18:57,136,322–57,150,410, 2 genes: AC100775.1, BOD1L2.
- chr18:78,976,555–79,002,677, 2 genes: LINC01896, SALL3.
- chr18:79,863,668–80,247,514, 15 genes: KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr19:58,386,400–58,605,223, 28 genes: RPS5, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.
- chr20:603,797–653,200, 2 genes: TCF15, SRXN1.
- chr20:17,209,060–17,226,146, 3 genes: RNU1-131P, AL359511.2, AL359511.3.
- chr21:41,870,633–41,882,300, 3 genes: AP001619.2, AP001619.1, AP001619.3.
- chr22:17,116,297–17,132,104, 2 genes: TMEM121B, LINC01664.
- chr22:50,568,861–50,801,309, 17 genes: CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 18,411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
